Somatic mutation profile of tumor specimen TCGA-BG-A3EW-01A (aliquot TCGA-BG-A3EW-01A-11D-A228-09) from TCGA case TCGA-BG-A3EW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.2 years (22,705 days).
Specimen TCGA-BG-A3EW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6208e986-1b64-4aee-a4be-82788d57969e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A3EW-11A (Solid Tissue Normal), aliquot TCGA-BG-A3EW-11A-22D-A228-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d2748d2-d444-466c-b1f2-8b7b0d612e0f

The open-access MAF lists 532 somatic variants for this specimen: 389 protein-altering or splice-affecting, 122 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 246, Silent 122, Frame Shift Del 88, Nonsense Mutation 24, Frame Shift Ins 19, Splice Site 9, Intron 8, RNA 6, 3'UTR 3, In Frame Del 2, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 42/118 reads (36%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 28/57 reads (49%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1414742926, CM053783, COSV100767742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 42/116 reads (36%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 66/136 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 100/118 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 16/26 reads (62%) | catalogued as rs749943218; called by mutect2, varscan2
- ACO2 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as rs61757465, COSV99347252; called by muse, mutect2, varscan2
- ACP7 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs975434362, COSV58700889; called by muse, mutect2, varscan2
- ACSL3 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs774856919, COSV100657908; called by muse, mutect2, varscan2
- ADA | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs776103734, COSV65741032; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766234741, COSV57861210; called by muse, mutect2, varscan2
- ADGRG2 | c.2506G>A p.A836T (on ENST00000379869 / NM_001079858.3; = p.A833T on NM_005756.4) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as rs760967425, COSV100492126; called by muse, mutect2, varscan2
- ADGRG4 | c.8137T>C p.Y2713H | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV99795091; called by muse, mutect2, varscan2
- ADNP | c.2594del p.K865Sfs*49 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV100823746; called by mutect2, varscan2
- ALDH1L1 | c.1591C>A p.R531S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200343595, COSV99856678; called by muse, mutect2, varscan2
- ALKAL2 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100732647; called by muse, mutect2, varscan2
- AMPD3 | c.466G>A p.A156T (on ENST00000396553 / NM_001025389.2; = p.A165T on NM_000480.3) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101158136; called by muse, mutect2, varscan2
- ANGEL2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.267); catalogued as rs1439933698, COSV100853931; called by muse, mutect2, varscan2
- ANGPTL1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV99328089; called by muse, mutect2, varscan2
- ANKRD20A4P | c.2386C>T p.L796F | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100628486; called by muse, mutect2, varscan2
- ANKRD28 | c.1121T>C p.F374S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV101080525; called by muse, mutect2
- ANKRD40 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99560445; called by muse, mutect2
- AP5S1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs146073355; called by muse, mutect2, varscan2
- ARHGAP21 | c.4585A>G p.R1529G | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100256026; called by muse, mutect2, varscan2
- ARHGEF11 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100809677; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ASB3 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99711889; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 42/163 reads (26%) | catalogued as rs761154268; called by mutect2, varscan2
- ATG7 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV100607091; called by muse, mutect2
- ATP8B2 | c.2965A>G p.I989V (on ENST00000672630; = p.I956V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.137); catalogued as COSV100527875; called by muse, mutect2, varscan2
- ATP9A | c.1072T>C p.Y358H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100124700; called by muse, mutect2
- B4GALNT4 | c.918dup p.R307Afs*98 | Frame Shift Ins (INS) | VAF 17/70 reads (24%) | catalogued as rs770737105; called by mutect2, varscan2
- BCAN | c.2326A>G p.S776G | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV61260356; called by muse, mutect2, varscan2
- BCL9L | c.3871G>A p.D1291N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.17); catalogued as COSV99419019; called by muse, mutect2, varscan2
- BCORL1 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99499066; called by muse, mutect2, varscan2
- BGLAP | c.243C>G p.D81E | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52744956, COSV99430985; called by mutect2, varscan2
- BMP2K | c.185T>A p.F62Y | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100621646; called by muse, mutect2, varscan2
- BPHL | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100984463; called by muse, mutect2, varscan2
- BTC | c.*1+1G>T | Splice Site (SNP) | VAF 4/94 reads (4%) | catalogued as COSV101201506; called by muse, mutect2
- C11orf1 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1555163377, COSV99499716; called by muse, mutect2, varscan2
- C12orf43 | c.43A>G p.N15D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99984494; called by muse, mutect2, varscan2
- C14orf39 | c.1349del p.P450Rfs*27 | Frame Shift Del (DEL) | VAF 39/105 reads (37%) | catalogued as COSV58783855; called by mutect2, pindel, varscan2
- C16orf87 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99587494; called by muse, mutect2, varscan2
- C2orf16 | c.5725C>T p.R1909C | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs762030907, COSV62677594; called by muse, mutect2, varscan2
- CAAP1 | c.571del p.I191Ffs*2 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs754356646, COSV61700397; called by mutect2, varscan2
- CACNA1I | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs771274219, COSV100359846; called by muse, mutect2, varscan2
- CACNG2 | c.762del p.V255Wfs*24 | Frame Shift Del (DEL) | VAF 69/184 reads (38%) | catalogued as COSV55632942; called by mutect2, pindel, varscan2
- CAMKK1 | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); catalogued as rs371110577, COSV99340176; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 56/130 reads (43%) | catalogued as rs760711956; called by mutect2, varscan2
- CAPRIN2 | c.2168C>A p.P723H | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99195420, COSV99195467; called by muse, mutect2, varscan2
- CCDC148 | c.1534A>G p.T512A | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99320109; called by muse, mutect2, varscan2
- CCDC47 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 35/129 reads (27%) | catalogued as COSV56724846; called by muse, mutect2, varscan2
- CCDC97 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs1259908553, COSV54189483; called by muse, mutect2, varscan2
- CDC73 | c.744C>A p.N248K | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866174269, COSV100813791; called by muse, mutect2, varscan2
- CDH18 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99933604; called by muse, mutect2, varscan2
- CDH23 | c.6817A>G p.S2273G | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99820152; called by muse, mutect2, varscan2
- CDH7 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs533419487, COSV59888578; called by muse, mutect2, varscan2
- CDK11B | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as rs770250152, COSV100477556, COSV58338811; called by muse, mutect2, varscan2
- CDKL5 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV101184219; called by muse, mutect2, varscan2
- CELSR3 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs769126116, COSV99373185; called by muse, mutect2, varscan2
- CEP164 | c.796A>G p.K266E | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV99633030; called by muse, mutect2, varscan2
- CEP95 | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101616305; called by muse, mutect2, varscan2
- CERS2 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99644290; called by muse, mutect2, varscan2
- CFAP46 | c.7222A>G p.I2408V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV99584430; called by mutect2, varscan2
- CHD9 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV68299560; called by muse, mutect2
- CHORDC1 | c.663del p.D222Mfs*36 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs1361626211; called by mutect2, pindel*, varscan2
- CLCN3 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100641654; called by muse, mutect2, varscan2
- CLEC14A | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100643532; called by muse, mutect2, varscan2
- CNNM1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100763814; called by muse, mutect2, varscan2
- COL4A3 | c.4566G>A p.W1522* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as COSV101170193; called by muse, mutect2, varscan2
- COPA | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1431254362, COSV54107585, COSV99615215; called by muse, mutect2, varscan2
- COX11 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as rs1015164309, COSV100174005, COSV54803683; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 51/265 reads (19%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRLF3 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100158350; called by muse, mutect2, varscan2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CWH43 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs141315226, COSV56937388, COSV99893295; called by muse, mutect2, varscan2
- CYB5R1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 103/145 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs777291289, COSV65916873; called by muse, mutect2, varscan2
- DAAM2 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs751120333, COSV51310983; called by muse, mutect2, varscan2
- DCAF11 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs749316385, COSV58109053; called by muse, mutect2, varscan2
- DCC | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as rs761293905, COSV100499154; called by muse, mutect2, varscan2
- DDIT4 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV100259093; called by muse, mutect2, varscan2
- DDX60 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV101190384; called by muse, mutect2, varscan2
- DEFB104B | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.017); catalogued as rs1223426259, COSV100296883; called by muse, mutect2, varscan2
- DNAH17 | c.10691C>T p.A3564V | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs935371184, COSV101101936; called by muse, mutect2, varscan2
- DNAH17 | c.10072C>T p.L3358F | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101101937; called by muse, mutect2, varscan2
- DOCK11 | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 6/143 reads (4%) | catalogued as COSV99353485; called by muse, mutect2
- DOCK3 | c.2530C>A p.R844S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV56515675, COSV99810759; called by muse, mutect2, varscan2
- DOK1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1248738230, COSV99284019; called by muse, mutect2, varscan2
- DPYSL3 | c.810del p.G271Efs*3 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as COSV58330462; called by mutect2, pindel, varscan2
- DSCAM | c.4711+1G>A p.X1571_splice | Splice Site (SNP) | VAF 27/72 reads (38%) | catalogued as COSV101259720; called by muse, mutect2, varscan2
- DYNC1I1 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100268039; called by muse, mutect2, varscan2
- DYNC2H1 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100518164; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs369293935; called by mutect2, varscan2
- EGLN2 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.441); catalogued as rs1555779251, COSV100393690; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs766700925; called by mutect2, varscan2
- EPB42 | c.1442C>T p.A481V (on ENST00000441366 / NM_001114134.2; = p.A511V on NM_000119.3) | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV100281907; called by muse, mutect2, varscan2
- ERAP2 | c.1572+1G>A p.X524_splice | Splice Site (SNP) | VAF 48/110 reads (44%) | catalogued as rs1253996388, COSV101163596; called by muse, mutect2, varscan2
- ERN2 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99891175; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 45/91 reads (49%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV7 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100339158; called by muse, mutect2, varscan2
- EVL | c.253C>T p.R85C (on ENST00000402714 / NM_001330221.2; = p.R87C on NM_016337.3) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs146349659; called by muse, mutect2, varscan2
- F13B | c.1271G>T p.R424I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.83); catalogued as COSV100803251; called by muse, mutect2
- FAM135B | c.2734A>G p.N912D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99421994; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM214B | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780611055, COSV100521261; called by muse, mutect2, varscan2
- FAM3D | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100716770; called by muse, mutect2, varscan2
- FAT4 | c.13001C>T p.T4334I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100628101; called by muse, mutect2, varscan2
- FHL2 | c.326T>G p.M109R | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as COSV100362871; called by muse, mutect2, varscan2
- FHOD1 | c.2263G>T p.A755S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV99263999; called by muse, mutect2, varscan2
- FLG | c.447del p.R151Gfs*43 | Frame Shift Del (DEL) | VAF 38/163 reads (23%) | catalogued as COSV64237488; called by mutect2, pindel, varscan2
- FLNB | c.1457A>G p.E486G | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV99912575; called by muse, mutect2, varscan2
- FLNC | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs962872361, COSV57955594; called by muse, mutect2, varscan2
- FRMD1 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV99349652; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as rs752538869; called by mutect2, varscan2
- FRMPD2 | c.946T>A p.L316M | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as COSV100563724; called by muse, mutect2, varscan2
- FRY | c.6581C>T p.T2194M | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs370549222; called by muse, mutect2, varscan2
- FSD2 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV100575083; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs756304971; called by mutect2, varscan2
- GCAT | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs138425464; called by muse, mutect2, varscan2
- GDF7 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55348113; called by muse, mutect2, varscan2
- GJA8 | c.1163C>A p.S388* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53788520, COSV99569264; called by muse, mutect2, varscan2
- GLI1 | c.1449G>T p.E483D | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV99953960; called by muse, mutect2
- GOLGA3 | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763833696, COSV99202586; called by muse, mutect2, varscan2
- GPR158 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs141963368, COSV66271925; called by muse, mutect2, varscan2
- GPR26 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV52933099; called by muse, mutect2, varscan2
- GREB1 | c.3499G>A p.A1167T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs371773393; called by muse, mutect2, varscan2
- GREB1 | c.4588C>T p.R1530* | Nonsense Mutation (SNP) | VAF 45/106 reads (42%) | catalogued as rs1395296430, COSV52184193; called by muse, mutect2, varscan2
- GRM6 | c.1536G>T p.E512D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99179539; called by muse, mutect2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GTF2H2C | c.349T>A p.L117M | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as COSV101053393; called by muse, varscan2
- GUCY1B1 | c.386A>T p.K129I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100025470; called by muse, mutect2, varscan2
- GZMH | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53538414; called by muse, mutect2
- H4C9 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62889659; called by muse, mutect2, varscan2
- HCFC1 | c.4263dup p.C1422Lfs*2 | Frame Shift Ins (INS) | VAF 76/184 reads (41%) | catalogued as rs782587798; called by mutect2, varscan2
- HCN4 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.397); catalogued as rs747467877, COSV56081253; ClinVar: uncertain significance; called by muse, mutect2
- HERC4 | c.614T>G p.L205R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99516815; called by muse, mutect2, varscan2
- HOXA1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749684801, COSV58029792; called by muse, mutect2, varscan2
- HSPG2 | c.7016G>T p.S2339I | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101020589; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 37/88 reads (42%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IFNW1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV101207608, COSV99061875; called by muse, mutect2, varscan2
- IFRD1 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.773); catalogued as COSV99133790; called by muse, mutect2, varscan2
- IGHD | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV101162834; called by muse, mutect2, varscan2
- IGLL1 | c.26del p.G9Afs*26 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs1569072706; called by mutect2, varscan2
- IGSF3 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as rs765984344, COSV100604470, COSV59596270; called by muse, mutect2, varscan2
- IL36G | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99381132; called by muse, mutect2, varscan2
- INHBA | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV54220961, COSV54224244; called by muse, mutect2, varscan2
- INPPL1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771815535, COSV53357347; called by muse, mutect2, varscan2
- INSRR | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV63872516; called by muse, mutect2, varscan2
- IRF2BPL | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.059); catalogued as rs1207842859, COSV53147331; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 44/108 reads (41%) | catalogued as rs761880048; called by mutect2, varscan2
- ITGA9 | c.1115A>G p.D372G | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764741915, COSV99292287; called by muse, mutect2, varscan2
- ITPR2 | c.5844T>G p.N1948K | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101189926; called by muse, mutect2, varscan2
- JAM3 | c.745dup p.V249Gfs*28 | Frame Shift Ins (INS) | VAF 48/98 reads (49%) | catalogued as rs763250381; called by mutect2, varscan2
- KCNH2 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs878853773, CM139892, COSV51188498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA0319 | c.3029G>T p.R1010M | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100985437; called by muse, mutect2, varscan2
- KIAA1210 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.929); catalogued as COSV101274049; called by muse, mutect2, varscan2
- KIAA1522 | c.662C>T p.A221V (on ENST00000373480 / NM_001198972.2; = p.A280V on NM_020888.3) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs754022301, COSV53864840; called by muse, mutect2, varscan2
- KIAA1755 | c.3394C>A p.Q1132K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99641809; called by muse, mutect2, varscan2
- KIF21B | c.4664C>T p.P1555L (on ENST00000422435 / NM_001252100.2; = p.P1542L on NM_017596.4) | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367842661; called by muse, mutect2, varscan2
- KMT2D | c.13948del p.E4650Sfs*16 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | catalogued as COSV56467227; called by mutect2, pindel, varscan2
- KMT2E | c.4082G>T p.G1361V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV99996077; called by muse, mutect2, varscan2
- KRT20 | c.205A>C p.N69H | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99391360; called by muse, mutect2, varscan2
- KRT77 | c.1667G>A p.G556D | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100527027; called by muse, mutect2, varscan2
- LAMP2 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs1131691290, COSV99568381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRPPRC | c.3653T>A p.L1218* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99580349; called by muse, mutect2, varscan2
- MACO1 | c.1790A>G p.Q597R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100975094; called by muse, mutect2, varscan2
- MAP3K10 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1261986128, COSV99454204; called by muse, mutect2, varscan2
- MBNL1 | c.973G>A p.A325T (on ENST00000282486 / NM_207293.2; = p.A307T on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.233); catalogued as COSV56826280; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs750092100; called by mutect2, varscan2
- MID1 | c.1681T>C p.S561P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100452352; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs750307488; called by mutect2, varscan2
- MMP1 | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100187887; called by muse, mutect2, varscan2
- MRPL18 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 80/251 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV100364797; called by muse, mutect2
- MTA1 | c.1913dup p.S639Lfs*18 | Frame Shift Ins (INS) | VAF 45/110 reads (41%) | catalogued as rs1555433939; called by mutect2, varscan2
- MYO18A | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1216874704, COSV99074504; called by muse, mutect2, varscan2
- MYOM2 | c.4229C>T p.S1410F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100037263; called by muse, mutect2, varscan2
- MYOT | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99524846; called by muse, mutect2, varscan2
- NAA40 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as COSV58161720; called by muse, mutect2, varscan2
- NEDD4 | c.3410G>A p.G1137D (on ENST00000508342 / NM_001284338.1; = p.G718D on NM_006154.4) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as rs1349095984, COSV100163585; called by muse, mutect2, varscan2
- NEK8 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs765364445, COSV99261728; called by muse, mutect2, varscan2
- NEPRO | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99868298; called by muse, mutect2, varscan2
- NPLOC4 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1391585016, COSV100480811; called by muse, mutect2, varscan2
- NRBP2 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV100589202; called by muse, mutect2, varscan2
- NUP153 | c.4202C>T p.T1401I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99467505; called by muse, mutect2, varscan2
- NUP210 | c.3478G>C p.V1160L | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV99595968; called by muse, mutect2, varscan2
- OR10K2 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100149456; called by muse, mutect2, varscan2
- OR10Z1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 49/218 reads (22%) | catalogued as rs755391413; called by mutect2, pindel, varscan2
- OR56B4 | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100337651; called by muse, mutect2, varscan2
- OR6K3 | c.820T>C p.Y274H (on ENST00000368146; = p.Y258H on NM_001005327.2) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs1249991672, COSV100933846; called by muse, mutect2
- OR8H1 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs114250300; called by muse, mutect2, varscan2
- OTX2 | c.207G>T p.E69D (on ENST00000408990 / NM_172337.3; = p.E77D on NM_021728.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100257851; called by muse, mutect2, varscan2
- P3H3 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377494942; called by muse, mutect2, varscan2
- PANK4 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99615940; called by muse, mutect2, varscan2
- PAPPA | c.3754C>T p.R1252W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs200530513, COSV100073557; called by muse, varscan2
- PCDHGB1 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as rs1238234703, COSV99535184; called by muse, mutect2, varscan2
- PCLO | c.14304G>A p.W4768* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as COSV61623635; called by muse, mutect2, varscan2
- PCSK6 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs759298704, COSV100083347; called by muse, mutect2
- PDE3A | c.3329C>T p.S1110L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs151154069; called by muse, mutect2, varscan2
- PDZK1 | c.1337G>A p.S446N | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100572405; called by muse, mutect2, varscan2
- PEAK3 | c.62A>G p.Q21R | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100574311; called by muse, mutect2, varscan2
- PEX2 | c.116A>C p.Q39P | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as rs1427212561, COSV100824750; called by muse, mutect2, varscan2
- PFKP | c.1492C>A p.H498N | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV101127132; called by muse, varscan2
- PGD | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs181999445, COSV54623785; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs769717544; called by mutect2, varscan2
- PIGR | c.1320G>A p.W440* | Nonsense Mutation (SNP) | VAF 29/187 reads (16%) | catalogued as COSV100732477; called by muse, mutect2, varscan2
- PLCD3 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100504184; called by muse, mutect2, varscan2
- PLCE1 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs754397478, COSV53376651; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs782247826; called by mutect2, varscan2
- PNLDC1 | c.1224+1G>A p.X408_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as rs771497671, COSV51707699; called by muse, varscan2
- POU3F4 | c.133G>T p.G45* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as COSV100937195, COSV64541522; called by muse, mutect2, varscan2
- PPARGC1B | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.097); catalogued as rs760246140, COSV58527032; called by muse, mutect2, varscan2
- PPP1R3F | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); catalogued as rs782230627, COSV50017740, COSV50019639; called by muse, mutect2, varscan2
- PRAG1 | c.1838C>A p.P613H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs1451588508, COSV100422067; called by muse, mutect2, varscan2
- PREX1 | c.1019A>T p.N340I | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906168; called by muse, mutect2, varscan2
- PRG3 | c.530G>C p.W177S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99755869; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | catalogued as rs537061158; called by mutect2, varscan2
- PSAP | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs202125074; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as COSV99194092; called by mutect2, pindel, varscan2
- PSME2 | c.126C>A p.Y42* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV99395574; called by muse, mutect2, varscan2
- PSME4 | c.4973G>T p.R1658L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101122760, COSV66367242; called by muse, mutect2, varscan2
- PTPRJ | c.415T>C p.W139R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101394828; called by muse, mutect2
- PTPRN2 | c.2977-2A>G p.X993_splice | Splice Site (SNP) | VAF 34/109 reads (31%) | catalogued as COSV101234085; called by muse, mutect2, varscan2
- PXDNL | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.637); catalogued as rs1471212956, COSV100682934; called by muse, mutect2, varscan2
- RABEP1 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99336479; called by muse, mutect2, varscan2
- RAC2 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as COSV99969447; called by muse, mutect2, varscan2
- RANBP2 | c.1310T>G p.L437R | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99311784; called by muse, varscan2
- RBM12 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1184014451, COSV100467322; called by muse, mutect2, varscan2
- RBMS3 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV56176308; called by muse, mutect2, varscan2
- RDH5 | c.718del p.A240Pfs*7 | Frame Shift Del (DEL) | VAF 33/82 reads (40%) | catalogued as rs753378940, CM991095; called by mutect2, pindel, varscan2
- RFXAP | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV99715144; called by muse, mutect2
- RNF183 | c.42del p.V15Sfs*33 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as COSV52907313; called by pindel, varscan2
- RTN1 | c.2069T>C p.L690P | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99955250; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs765867975; called by mutect2, varscan2
- SEC16B | c.1299dup p.S434Qfs*14 | Frame Shift Ins (INS) | VAF 23/117 reads (20%) | catalogued as rs768388757; called by mutect2, varscan2
- SEC31A | c.3155T>C p.F1052S (on ENST00000355196 / NM_001318120.1; = p.F1013S on NM_016211.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.247); catalogued as rs767561674; called by muse, mutect2, varscan2
- SELE | c.1661A>G p.N554S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100324668; called by muse, mutect2, varscan2
- SGO1 | c.1639C>A p.P547T (on ENST00000263753 / NM_001012410.5; = p.P278T on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | PolyPhen benign (0.015); catalogued as COSV99768249; called by muse, mutect2, varscan2
- SIMC1 | c.119G>A p.R40H (on ENST00000443967 / NM_001308196.1; = p.R59H on NM_001308195.2) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as rs532398297, COSV100365385; called by muse, mutect2, varscan2
- SIN3B | c.2014T>A p.Y672N | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99931583; called by muse, mutect2, varscan2
- SIPA1L2 | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759917411, COSV99477800; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC39A13 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs374739509; called by muse, varscan2
- SLC39A4 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV99433212; called by muse, mutect2, varscan2
- SLC7A6 | c.878T>A p.L293Q | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV99546518; called by muse, mutect2, varscan2
- SMG8 | c.358G>T p.G120* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99958755; called by muse, mutect2, varscan2
- SNRPN | c.420+2T>C p.X140_splice | Splice Site (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100578075, COSV57596417; called by muse, mutect2, varscan2
- SPG7 | c.1093G>T p.A365S (on ENST00000268704; = p.A372S on NM_003119.4) | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.451); catalogued as rs1438315244, COSV99244793; called by muse, mutect2, varscan2
- SPIRE1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453744342, COSV100563549; called by muse, mutect2, varscan2
- SPTB | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs769871954, COSV101071900; called by muse, mutect2, varscan2
- SPTBN5 | c.2927A>G p.E976G | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100311121; called by muse, mutect2
- SSH1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs1264328816, COSV58455194; called by muse, mutect2
- SSH3 | c.1738C>A p.L580I | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100354477; called by muse, mutect2, varscan2
- STAT3 | c.1093A>C p.K365Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99232644; called by muse, mutect2, varscan2
- STX2 | c.800T>A p.I267N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99892629; called by muse, mutect2, varscan2
- STX8 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV100111027; called by muse, mutect2, varscan2
- SUOX | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 58/146 reads (40%) | catalogued as COSV56268427; called by muse, mutect2, varscan2
- SYNE4 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV99430974; called by muse, mutect2, varscan2
- SZT2 | c.6370G>T p.E2124* (on ENST00000634258 / NM_001365999.1; = p.E2067* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 35/82 reads (43%) | catalogued as COSV100987054; called by muse, mutect2, varscan2
- TASOR2 | c.6296G>A p.S2099N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as COSV100050284; called by muse, varscan2
- TBC1D22B | c.530dup p.M178Nfs*22 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs757209781; called by mutect2, varscan2
- TCF20 | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs779463136, COSV59494113; called by muse, mutect2, varscan2
- TDRD5 | c.2200A>G p.T734A | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV99675928; called by muse, mutect2, varscan2
- TECPR1 | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as COSV101130388; called by muse, mutect2, varscan2
- TECPR2 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs1304825274, COSV100849917; called by muse, mutect2, varscan2
- TFDP3 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100033300; called by muse, mutect2, varscan2
- THSD7B | c.2363A>T p.E788V | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99747980; called by muse, varscan2
- TINAGL1 | c.181_183del p.D61del | In Frame Del (DEL) | VAF 42/91 reads (46%) | catalogued as rs1192018462; called by pindel, varscan2
- TLE1 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs372989218, COSV100915965; called by muse, mutect2, varscan2
- TLL1 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286090961, COSV99286820; called by muse, mutect2, varscan2
- TMEM190 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99404275; called by muse, mutect2, varscan2
- TMEM196 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101337424; called by muse, mutect2, varscan2
- TMEM9 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100947365; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4202T>A p.V1401D | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100835942; called by muse, mutect2, varscan2
- TNRC18 | c.4627dup p.R1543Pfs*10 | Frame Shift Ins (INS) | VAF 44/103 reads (43%) | catalogued as rs754233336; called by mutect2, varscan2
- TNS2 | c.3358G>T p.E1120* (on ENST00000314250 / NM_170754.4; = p.E1130* on NM_015319.2) | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100036650; called by muse, mutect2, varscan2
- TNXB | c.8759G>A p.R2920Q (on ENST00000647633; = p.R2673Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.778); catalogued as rs768698539, COSV100926157; called by muse, mutect2, varscan2
- TOX4 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99398154; called by muse, mutect2, varscan2
- TPCN1 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs200644632, COSV59237196; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1225T>A p.L409M | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV100389694; called by muse, mutect2, varscan2
- TRGV5 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 21/32 reads (66%) | catalogued as rs541092806; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIM7 | c.1004A>C p.E335A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); catalogued as COSV99220125; called by muse, mutect2, varscan2
- TRPM4 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs909581400, COSV53260427; called by muse, mutect2, varscan2
- TRPM6 | c.6046C>A p.P2016T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100666118; called by muse, mutect2, varscan2
- TRPM7 | c.1702A>G p.R568G | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV100539667; called by muse, mutect2, varscan2
- TRPV3 | c.1693T>C p.Y565H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1170616841, COSV100027612; called by muse, mutect2, varscan2
- TRRAP | c.8204A>G p.E2735G (on ENST00000359863 / NM_001244580.1; = p.E2717G on NM_003496.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV100722304; called by muse, mutect2, varscan2
- TSPOAP1 | c.1858T>C p.C620R | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs1567846684, COSV99270695; called by muse, mutect2, varscan2
- TSPYL6 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1431602063, COSV57814443; called by muse, mutect2, varscan2
- TTC12 | c.795del p.I266Lfs*4 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs1555145313; called by mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.80041C>T p.R26681C (on ENST00000591111; = p.R19257C on NM_003319.4) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | PolyPhen possibly damaging (0.809); catalogued as rs774978209, COSV100604455, COSV60005904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2G2 | c.365C>G p.S122W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100446086; called by muse, mutect2, varscan2
- UMOD | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.363); catalogued as COSV100208204; called by muse, mutect2
- UNC79 | c.1090C>T p.Q364* (on ENST00000393151 / NM_001346218.2; = p.Q187* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99827023; called by muse, mutect2, varscan2
- UROC1 | c.161del p.P54Rfs*32 | Frame Shift Del (DEL) | VAF 38/115 reads (33%) | catalogued as rs764241328, COSV52031695; called by mutect2, pindel, varscan2
- USP6NL | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1190896155, COSV53209292; called by muse, mutect2, varscan2
- UTP4 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as rs755772687, COSV58733848; called by muse, mutect2, varscan2
- VANGL2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs201184424, COSV63604303; called by muse, mutect2
- VANGL2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760434234, COSV63604390; called by muse, mutect2, varscan2
- VARS2 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99461688; called by muse, mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VPS13A | c.4114+2T>C p.X1372_splice | Splice Site (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100652486; called by muse, mutect2, varscan2
- WDR53 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as rs767475266, COSV100218046; called by muse, mutect2, varscan2
- WEE2 | c.1564T>C p.S522P | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV101187659; called by muse, mutect2, varscan2
- WNT9A | c.403C>G p.H135D | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99688140; called by muse, mutect2
- WRN | c.1627T>C p.Y543H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV99988724; called by muse, mutect2, varscan2
- XKR8 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772993872, COSV100871918; called by muse, mutect2, varscan2
- YTHDC1 | c.1574G>A p.R525H (on ENST00000344157 / NM_001031732.4; = p.R507H on NM_133370.4) | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs771100713, COSV100704660; called by muse, mutect2, varscan2
- ZBTB20 | c.632C>T p.T211M (on ENST00000474710 / NM_001164342.2; = p.T138M on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61846098, COSV61860951; called by muse, mutect2, varscan2
- ZBTB41 | c.392T>A p.V131E | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100963016; called by muse, mutect2
- ZDHHC4 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs977295777, COSV100253888; called by muse, mutect2, varscan2
- ZFC3H1 | c.4834C>T p.H1612Y | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101110456; called by muse, mutect2, varscan2
- ZFHX3 | c.2096del p.G699Afs*125 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs753977275, COSV51729347; called by pindel, varscan2
- ZNF169 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs369258975; called by muse, mutect2, varscan2
- ZNF17 | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100299997; called by muse, mutect2, varscan2
- ZNF20 | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs776799535, COSV100502970; called by muse, mutect2, varscan2
- ZNF304 | c.1011C>A p.C337* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV99988551; called by muse, mutect2, varscan2
- ZNF317 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs573363167, COSV56110516; called by muse, mutect2, varscan2
- ZNF330 | c.532T>C p.C178R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99522463; called by muse, mutect2, varscan2
- ZNF382 | c.1381del p.E461Kfs*84 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as COSV53086628, COSV53090943; called by mutect2, pindel, varscan2
- ZNF516 | c.3111del p.V1038Sfs*122 | Frame Shift Del (DEL) | VAF 25/138 reads (18%) | catalogued as COSV71586708, COSV71587288; called by mutect2, pindel, varscan2
- ZNF526 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs148408615; called by muse, mutect2
- ZNF687 | c.2815del p.R939Vfs*10 | Frame Shift Del (DEL) | VAF 75/213 reads (35%) | catalogued as rs749403447; called by mutect2, pindel, varscan2
- ZNF785 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs368353551; called by muse, mutect2, varscan2
- ZSCAN20 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100792545; called by muse, varscan2
- ZSCAN5B | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV100748406; called by muse, mutect2, varscan2
- ZWINT | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100571500; called by muse, mutect2, varscan2
- AC092143.1 | c.1858dup p.L620Pfs*83 | Frame Shift Ins (INS) | VAF 59/173 reads (34%) | called by mutect2, pindel, varscan2
- AKR1B10 | c.730del p.T244Pfs*6 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- APOB | c.4321dup p.E1441Gfs*19 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- BAZ2B | c.1594del p.S532Pfs*4 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- BRD1 | c.1474del p.L492Cfs*24 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | called by mutect2, pindel, varscan2
- C1orf116 | c.1719del p.C574Vfs*20 | Frame Shift Del (DEL) | VAF 34/146 reads (23%) | called by mutect2, pindel, varscan2
- CCAR1 | c.2416del p.S806Afs*85 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- CCAR2 | c.761_762del p.S254* | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- CD93 | c.943del p.A315Pfs*273 | Frame Shift Del (DEL) | VAF 53/155 reads (34%) | called by mutect2, pindel, varscan2
- CENPE | c.5986del p.I1996Lfs*7 | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | called by mutect2, pindel, varscan2
- CHCHD6 | c.137del p.P46Lfs*15 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- CHD1 | c.4509del p.K1503Nfs*15 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | called by mutect2, pindel, varscan2
- CMIP | c.964del p.R322Gfs*31 (on ENST00000537098 / NM_198390.2; = p.R228Gfs*31 on NM_030629.3) | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- CWH43 | c.2013del p.F671Lfs*22 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- DOCK7 | c.4128del p.V1377Cfs*5 (on ENST00000635253 / NM_001367561.1; = p.V1346Cfs*5 on NM_033407.3) | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | called by mutect2, pindel, varscan2
- EML4 | c.2600del p.K867Sfs*10 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | called by mutect2, pindel, varscan2
- FAM47C | c.1509del p.K504Rfs*321 | Frame Shift Del (DEL) | VAF 58/210 reads (28%) | called by mutect2, pindel, varscan2
- FAM83E | c.359_360del p.S120Cfs*46 | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | called by pindel, varscan2
- FBH1 | c.2872del p.T958Qfs*23 (on ENST00000362091 / NM_178150.3; = p.T1009Qfs*23 on NM_032807.4) | Frame Shift Del (DEL) | VAF 48/132 reads (36%) | called by mutect2, pindel, varscan2
- GALNT8 | c.1763del p.X588_splice | Splice Site (DEL) | VAF 37/88 reads (42%) | called by mutect2, pindel, varscan2
- GLMP | c.878dup p.R294Pfs*35 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | called by mutect2, varscan2
- HPS1 | c.2095del p.L699Cfs*26 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- IFRD2 | c.376del p.D126Mfs*16 | Frame Shift Del (DEL) | VAF 49/84 reads (58%) | called by mutect2, pindel, varscan2
- IGHV4-28 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- IGKV2D-24 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRCC1 | c.484del p.R162Gfs*28 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | called by mutect2, pindel, varscan2
- LCP2 | c.1360del p.T454Qfs*73 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | called by mutect2, pindel, varscan2
- LRBA | c.6031del p.T2011Qfs*11 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- MAP4 | c.2878del p.T960Qfs*35 | Frame Shift Del (DEL) | VAF 42/111 reads (38%) | called by mutect2, pindel, varscan2
- MYO16 | c.2607del p.K869Nfs*6 | Frame Shift Del (DEL) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- NFE2L2 | c.88_90del p.L30del | In Frame Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- NRDC | c.616del p.T206Lfs*17 | Frame Shift Del (DEL) | VAF 40/101 reads (40%) | called by mutect2, varscan2
- OR5P3 | c.533del p.F178Sfs*8 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- OSBPL7 | c.1754del p.P585Lfs*18 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- PI4K2A | c.1274del p.G425Afs*4 | Frame Shift Del (DEL) | VAF 34/102 reads (33%) | called by mutect2, pindel, varscan2
- PNPLA7 | c.2723del p.P908Rfs*14 | Frame Shift Del (DEL) | VAF 59/161 reads (37%) | called by mutect2, pindel, varscan2
- PRR35 | c.146dup p.S50Vfs*35 | Frame Shift Ins (INS) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- PTCD1 | c.2050del p.D684Tfs*39 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- RIMKLA | c.620del p.G207Afs*4 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | called by mutect2, pindel, varscan2
- ROBO4 | c.2604del p.S869Afs*5 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- RUBCNL | c.501del p.F167Lfs*6 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- SIK2 | c.2046del p.H682Qfs*58 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- SLC13A1 | c.1129del p.S377Qfs*16 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- SLC25A22 | c.464del p.G155Vfs*19 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- SLIT3 | c.3338dup p.P1114Tfs*76 | Frame Shift Ins (INS) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- SLTM | c.1539dup p.E514Rfs*6 | Frame Shift Ins (INS) | VAF 40/109 reads (37%) | called by mutect2, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, varscan2
- SP100 | c.2282del p.K761Rfs*40 | Frame Shift Del (DEL) | VAF 30/64 reads (47%) | called by mutect2, varscan2
- TBC1D32 | c.1773del p.K591Nfs*40 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 37/100 reads (37%) | called by mutect2, varscan2
- UACA | c.136del p.D46Mfs*2 | Frame Shift Del (DEL) | VAF 42/115 reads (37%) | called by mutect2, pindel, varscan2
- USP14 | c.773del p.T258Kfs*67 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- WASHC4 | c.842dup p.N281Kfs*2 | Frame Shift Ins (INS) | VAF 27/92 reads (29%) | called by mutect2, pindel, varscan2
- ZFAND2A | c.203del p.K68Rfs*? | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | called by mutect2, pindel, varscan2
- ZNF749 | c.649dup p.T217Nfs*3 | Frame Shift Ins (INS) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- AANAT | c.15C>T p.S5= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs201897313, COSV99166198; called by muse, mutect2, varscan2
- ABCB7 | c.867C>T p.C289= (on ENST00000373394 / NM_001271696.3; = p.C290= on NM_004299.6) | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs769487666, COSV53719399; called by muse, mutect2, varscan2
- AC008397.2 | c.312C>T p.G104= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs776286183, COSV99441504; called by muse, mutect2, varscan2
- ACVRL1 | c.1413C>T p.C471= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1301762186, CM062405, COSV101187843; called by muse, mutect2, varscan2
- ADD2 | c.1932G>A p.P644= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs115476558, COSV100035262; called by muse, mutect2, varscan2
- ARGLU1 | c.555C>T p.A185= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as rs370990793, COSV62271651; called by muse, mutect2, varscan2
- ARHGAP30 | c.1707G>A p.E569= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100920192; called by muse, mutect2, varscan2
- ATRX | c.5364G>A p.Q1788= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV100970492, COSV64880095; called by muse, mutect2
- C10orf71 | c.1683C>T p.P561= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs750258938, COSV60514944; called by muse, mutect2, varscan2
- CAB39L | c.993C>T p.D331= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV100759535, COSV61716243; called by muse, mutect2, varscan2
- CASZ1 | c.4827G>A p.A1609= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100985217; called by muse, varscan2
- CCDC15 | c.987G>A p.L329= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100776950; called by muse, mutect2, varscan2
- CCDC96 | c.1371C>T p.N457= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV59508459; called by muse, mutect2
- CD93 | c.1728T>C p.T576= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99849082; called by muse, mutect2, varscan2
- CDH16 | c.235C>T p.L79= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100233779; called by muse, mutect2
- CELSR2 | c.1992T>C p.G664= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV99603541; called by muse, mutect2, varscan2
- CHD1 | c.237G>A p.P79= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as COSV99399316; called by muse, mutect2, varscan2
- CLASP1 | c.1356C>T p.N452= | Silent (SNP) | VAF 42/79 reads (53%) | catalogued as rs1465630497, COSV99754080; called by muse, mutect2, varscan2
- CRTAC1 | c.274C>T p.L92= | Silent (SNP) | VAF 68/134 reads (51%) | catalogued as rs1189893478, COSV100085329; called by muse, mutect2, varscan2
- CTNNB1 | c.354T>C p.H118= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100846199; called by muse, mutect2, varscan2
- DAG1 | c.333C>T p.D111= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1221719616, COSV100444833; called by muse, mutect2, varscan2
- DDC | c.1384C>A p.R462= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV100779202; called by muse, mutect2, varscan2
- DNA2 | c.1818C>T p.Y606= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100622479; called by muse, mutect2, varscan2
- DNAJA2 | c.1230C>A p.A410= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100398833; called by muse, mutect2, varscan2
- DPYD | c.2067G>A p.E689= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100928894; called by muse, mutect2, varscan2
- DSG2 | c.669C>A p.T223= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV99853010; called by muse, mutect2, varscan2
- ENPP1 | c.1620A>G p.V540= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV100719480; called by muse, mutect2
- ENPP7 | c.297C>T p.Y99= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV100093311; called by muse, mutect2, varscan2
- EPHX3 | c.249G>A p.S83= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99650277, COSV99650336; called by muse, mutect2, varscan2
- ERC1 | c.1413G>A p.V471= (on ENST00000360905 / NM_178040.4; = p.V443= on NM_178039.4) | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100705849; called by muse, mutect2, varscan2
- ERCC3 | c.2304G>A p.A768= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1354994770, COSV99572985; called by muse, mutect2, varscan2
- FAT1 | c.7512C>T p.N2504= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1002759839, COSV101499257; called by muse, mutect2, varscan2
- FBN1 | c.4821T>A p.I1607= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV100354524; called by muse, mutect2, varscan2
- GALNT14 | c.1023C>T p.Y341= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs553549873, COSV100204408, COSV61104178; called by muse, mutect2, varscan2
- GDF2 | c.888T>C p.G296= | Silent (SNP) | VAF 38/108 reads (35%) | called by muse, mutect2, varscan2
- GGT7 | c.213A>G p.P71= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100321860; called by muse, mutect2, varscan2
- GNAS | c.441T>C p.Y147= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV99669677; called by muse, mutect2, varscan2
- GRIN1 | c.2640T>C p.F880= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV100160112; called by muse, mutect2
- GTF3C1 | c.3159G>A p.V1053= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs752811341, COSV100649225; called by muse, mutect2, varscan2
- HCFC1 | c.2577C>A p.P859= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100128765; called by muse, mutect2, varscan2
- HELB | c.540G>A p.Q180= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99921756; called by muse, mutect2, varscan2
- ICE1 | c.1245A>G p.T415= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99664357; called by muse, mutect2, varscan2
- INAVA | c.1338C>A p.P446= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV100949947; called by muse, mutect2, varscan2
- IRAK2 | c.1797T>C p.N599= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as rs1438088056, COSV99843883; called by muse, mutect2, varscan2
- ITM2C | c.783G>A p.T261= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as rs769332366, COSV100419591; called by muse, mutect2, varscan2
- KIF4A | c.2103A>G p.R701= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100979473; called by muse, mutect2, varscan2
- KMT2C | c.3234C>T p.C1078= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as rs759975163, COSV51498538; called by muse, mutect2, varscan2
- KRTAP9-4 | c.336C>T p.C112= | Silent (SNP) | VAF 97/237 reads (41%) | catalogued as COSV100484874; called by muse, mutect2, varscan2
- LAMC3 | c.822C>T p.N274= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as rs141439509; called by muse, varscan2
- LAMC3 | c.1836C>A p.T612= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1364633032, COSV100735938; called by muse, mutect2, varscan2
- LINGO2 | c.1509C>T p.F503= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as rs369907065; called by muse, mutect2, varscan2
- LNPEP | c.2061G>A p.V687= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV99183511; called by muse, mutect2, varscan2
- LRRK1 | c.2163G>T p.V721= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as COSV99438952; called by muse, mutect2, varscan2
- LSM11 | c.648G>A p.R216= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs1300114235, COSV99643917; called by muse, mutect2, varscan2
- MAB21L4 | c.51G>A p.L17= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as rs893649792, COSV100278462; called by muse, mutect2, varscan2
- MAML2 | c.2055A>G p.P685= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as rs1490613176, COSV101594084; called by muse, varscan2
- MAP3K13 | c.1701C>T p.S567= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV99406853; called by muse, mutect2, varscan2
- MROH9 | c.1620G>A p.Q540= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as COSV100882732; called by muse, mutect2, varscan2
- MRPS31 | c.225T>C p.V75= | Silent (SNP) | VAF 52/111 reads (47%) | catalogued as COSV100062155; called by muse, mutect2, varscan2
- MUC17 | c.10230G>T p.P3410= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as rs771641488, COSV100072639; called by muse, mutect2, varscan2
- MX2 | c.1431C>T p.H477= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100415865; called by muse, mutect2, varscan2
- MYH6 | c.1198C>T p.L400= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as rs1275352739, COSV100676431; called by muse, mutect2
- MYL3 | c.477G>A p.T159= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs148365503, COSV99439427; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYL7 | c.465G>A p.A155= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs138710066; called by muse, mutect2, varscan2
- NCKAP5L | c.90C>T p.C30= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV100258603; called by muse, mutect2, varscan2
- NEXMIF | c.4251T>C p.G1417= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs757785426, COSV99280361; called by muse, mutect2, varscan2
- NFYA | c.135A>G p.S45= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs1317152451, COSV100399622; called by muse, mutect2, varscan2
- NOS1 | c.3225C>T p.N1075= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs541417685, COSV100500358; called by muse, mutect2, varscan2
- NOTCH3 | c.4479C>T p.C1493= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV54637533; called by muse, mutect2, varscan2
- NPBWR1 | c.684C>T p.C228= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV100488179; called by muse, mutect2, varscan2
- NUAK1 | c.495T>C p.A165= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99776858; called by muse, mutect2, varscan2
- OR51E2 | c.345G>T p.L115= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV101211331; called by muse, mutect2, varscan2
- OR51M1 | c.600C>A p.A200= | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as COSV100150193; called by muse, mutect2, varscan2
- OR9Q1 | c.252G>A p.V84= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV100109713; called by muse, mutect2, varscan2
- PABPN1L | c.373C>T p.L125= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV56352084, COSV99967537; called by muse, mutect2, varscan2
- PAXIP1 | c.1356G>A p.Q452= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV101249300; called by muse, mutect2, varscan2
- PCDH19 | c.540G>A p.T180= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as rs368094294, COSV55258074; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB4 | c.1902A>G p.A634= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as rs528365920, COSV99522018; called by muse, mutect2, varscan2
- PCNX1 | c.6357C>T p.A2119= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV99455113; called by muse, mutect2, varscan2
- PDS5A | c.2700T>C p.A900= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV100337278; called by muse, mutect2, varscan2
- PHACTR3 | c.471C>A p.P157= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100732424; called by muse, mutect2, varscan2
- PIKFYVE | c.2157T>C p.T719= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100010329; called by muse, mutect2, varscan2
- PKHD1L1 | c.9C>T p.H3= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as rs1319538893, COSV101005915; called by muse, mutect2, varscan2
- PNPLA6 | c.4065G>A p.K1355= (on ENST00000414982 / NM_001166111.2; = p.K1307= on NM_006702.5) | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV99653464; called by muse, mutect2, varscan2
- POFUT2 | c.1083C>A p.L361= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV100499196; called by muse, mutect2, varscan2
- POM121C | c.2856T>C p.A952= (on ENST00000607367; = p.A710= on NM_001099415.3) | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV99992593; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2889C>T p.L963= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV51478555; called by muse, mutect2, varscan2
- RADX | c.447C>T p.C149= | Silent (SNP) | VAF 51/117 reads (44%) | catalogued as COSV100998812; called by muse, mutect2, varscan2
- RALGDS | c.723C>A p.A241= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV100924364; called by muse, mutect2, varscan2
- REEP4 | c.393C>T p.S131= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as rs772876078, COSV100098099, COSV57941995; called by muse, mutect2, varscan2
- RGS12 | c.4182C>T p.G1394= (on ENST00000336727; = p.G746= on NM_198227.2) | Silent (SNP) | VAF 60/121 reads (50%) | catalogued as COSV100122766; called by muse, mutect2, varscan2
- RGS22 | c.2079T>C p.S693= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100693143; called by muse, mutect2, varscan2
- RIMBP2 | c.2115C>T p.D705= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs761677291, COSV55467808; called by muse, mutect2, varscan2
- RIPK1 | c.582G>A p.A194= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs372626426; called by muse, mutect2, varscan2
- RNF213 | c.11631C>A p.P3877= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100300198; called by muse, mutect2, varscan2
- RPS16 | c.282C>A p.A94= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV99261805; called by muse, mutect2, varscan2
- SBK2 | c.177C>T p.D59= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs778217917, COSV100705088; called by muse, mutect2, varscan2
- SLC2A6 | c.939C>T p.D313= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs370840549; called by muse, mutect2, varscan2
- SMG1 | c.904T>C p.L302= | Silent (SNP) | VAF 10/268 reads (4%) | catalogued as COSV101245592; called by muse, mutect2
- SON | c.3951C>A p.A1317= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99277622; called by muse, mutect2, varscan2
- SORL1 | c.4248C>A p.P1416= | Silent (SNP) | VAF 80/150 reads (53%) | catalogued as COSV99493423; called by muse, mutect2, varscan2
- SPATA22 | c.396T>C p.C132= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs1354725958, COSV99279209; called by muse, mutect2, varscan2
- SPINK5 | c.537T>C p.N179= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99806483; called by muse, mutect2, varscan2
- SPTA1 | c.96G>A p.L32= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV100934412, COSV100934689; called by muse, mutect2, varscan2
- SUGP2 | c.2934T>C p.H978= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100431758; called by muse, mutect2, varscan2
- SULT1E1 | c.330T>C p.P110= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs892853483, COSV99894864; called by muse, mutect2, varscan2
- SYTL3 | c.84T>A p.V28= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV99791786; called by muse, mutect2, varscan2
- TACO1 | c.297T>C p.P99= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV99366462; called by muse, mutect2, varscan2
- TECPR1 | c.675C>T p.D225= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs369846066; called by muse, mutect2, varscan2
- TGM6 | c.1146G>A p.V382= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV99171748; called by muse, mutect2, varscan2
- TMEM131 | c.1344T>C p.P448= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99487355; called by muse, mutect2, varscan2
- TRIM55 | c.1293T>G p.P431= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99396702; called by muse, mutect2, varscan2
- TSSK6 | c.516C>T p.C172= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as rs1285017345, COSV99389006; called by muse, mutect2, varscan2
- TULP4 | c.2247G>A p.R749= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- WBP2NL | c.807G>A p.P269= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs1266718520, COSV60919080; called by muse, mutect2, varscan2
- WWC1 | c.3000C>A p.T1000= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV99514739; called by muse, mutect2
- WWP1 | c.2538A>G p.L846= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99616071; called by mutect2, varscan2
- YIPF4 | c.648T>C p.G216= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs1200899093, COSV99479810; called by muse, mutect2, varscan2
- ZBTB20 | c.1362G>A p.K454= (on ENST00000474710 / NM_001164342.2; = p.K381= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV100613404; called by muse, mutect2, varscan2
- ZNF497 | c.1353C>T p.F451= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99568274; called by muse, varscan2
- ZNF793 | c.228C>T p.C76= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as COSV101495646; called by muse, mutect2, varscan2
- ZSCAN20 | c.273G>A p.L91= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV100792544; called by muse, varscan2
- AK1 | c.8-338C>T | Intron (SNP) | VAF 31/118 reads (26%) | catalogued as COSV99802361; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826245 del T | 3'Flank (DEL) | VAF 26/68 reads (38%) | catalogued as rs768711387; called by mutect2, varscan2
- AP001425.1 | chr21:38208431 G>C | 5'Flank (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 15/31 reads (48%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- DEPDC5 | c.*1009A>T | 3'UTR (SNP) | VAF 32/84 reads (38%) | catalogued as COSV99834991; called by muse, mutect2, varscan2
- KCNIP4 | c.62-421181T>G | Intron (SNP) | VAF 18/54 reads (33%) | catalogued as COSV101184988; called by muse, mutect2, varscan2
- KDM5A | c.4867-528G>A | Intron (SNP) | VAF 20/60 reads (33%) | catalogued as rs374407213, COSV101238728; called by muse, mutect2, varscan2
- KIF16B | c.3498+3228A>G | Intron (SNP) | VAF 37/89 reads (42%) | catalogued as rs1048750546, COSV100734072; called by muse, mutect2, varscan2
- KIR3DX1 | n.561T>C | RNA (SNP) | VAF 56/146 reads (38%) | catalogued as COSV99683199; called by muse, mutect2, varscan2
- KLHL6 | c.*1C>T | 3'UTR (SNP) | VAF 44/111 reads (40%) | catalogued as rs1457222578, COSV58067072; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.771C>A | RNA (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- MIR373 | n.20C>T | RNA (SNP) | VAF 26/94 reads (28%) | catalogued as rs745638801; called by muse, mutect2, varscan2
- MIR548A1 | n.22T>C | RNA (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- NBR2 | n.414G>A | RNA (SNP) | VAF 75/180 reads (42%) | catalogued as rs532260289; called by muse, mutect2, varscan2
- NMNAT2 | c.86-10914C>T | Intron (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99679866; called by muse, mutect2, varscan2
- P2RX3 | c.-2G>A | 5'UTR (SNP) | VAF 64/137 reads (47%) | catalogued as COSV99554851; called by muse, mutect2, varscan2
- SRSF10 | c.*3471A>G | 3'UTR (SNP) | VAF 136/290 reads (47%) | called by muse, mutect2, varscan2
- SSPOP | n.7015G>A | RNA (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100022351; called by muse, mutect2, varscan2
- TPM3 | c.244-6786A>T | Intron (SNP) | VAF 36/169 reads (21%) | catalogued as COSV99666252; called by muse, mutect2, varscan2
- TRIM61 | c.526-1938G>A | Intron (SNP) | VAF 26/51 reads (51%) | catalogued as rs1413217820, COSV100255982; called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280722 T>A | 5'Flank (SNP) | VAF 39/124 reads (31%) | called by muse, mutect2, varscan2
